Somatic mutation profile of tumor specimen TCGA-QH-A6X9-01A (aliquot TCGA-QH-A6X9-01A-12D-A32B-08) from TCGA case TCGA-QH-A6X9, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 73.9 years (26,992 days).
Specimen TCGA-QH-A6X9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7f0059fa-415c-4fbe-b667-daec8bd21491.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QH-A6X9-10B (Blood Derived Normal), aliquot TCGA-QH-A6X9-10B-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/251b68f5-3f01-479c-906b-2951a857da5f

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 13, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/62 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.470T>A p.V157D | Missense Mutation (SNP) | VAF 53/65 reads (82%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691023, CM138009, CM161671, COSV52675572, COSV52699845, COSV52722122; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABHD13 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as rs770118849, COSV101024008, COSV101024212; called by muse, mutect2, varscan2
- ACACB | c.4510C>T p.R1504W | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759522981, COSV100622215; called by muse, mutect2, varscan2
- ADSL | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV53408311; called by muse, mutect2
- AFDN | c.892G>A p.A298T | Missense Mutation (SNP) | VAF 12/123 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs764123133, COSV60045170; called by muse, mutect2
- DENND6A | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); catalogued as COSV60768177; called by muse, mutect2
- DMPK | c.1568G>T p.R523L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.565); catalogued as rs145245565, COSV52175791; called by muse, mutect2
- FAT3 | c.9089A>T p.D3030V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs1189757010, COSV99961132; called by muse, mutect2, varscan2
- GGT5 | c.1370G>T p.R457M | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.094); catalogued as COSV54069190, COSV99571213; called by muse, mutect2, varscan2
- H2AC6 | c.386G>A p.G129D | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV58415249; called by muse, mutect2, varscan2
- H2BC14 | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); catalogued as COSV100297462; called by muse, mutect2, varscan2
- HSH2D | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99507038; called by muse, mutect2, varscan2
- IHH | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99838575; called by muse, mutect2, varscan2
- IL1RL1 | c.180G>C p.Q60H | Missense Mutation (SNP) | VAF 54/187 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV52121747; called by muse, mutect2, varscan2
- KLHDC3 | c.517A>G p.K173E | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.676); catalogued as COSV99763530; called by muse, mutect2, varscan2
- MTSS1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100274295; called by muse, mutect2, varscan2
- MYH4 | c.4199G>A p.R1400H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as rs369407729; called by muse, mutect2, varscan2
- NYX | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); catalogued as rs748302686, COSV100699350; called by muse, mutect2, varscan2
- OAZ1 | c.652T>C p.F218L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100457199; called by muse, mutect2, varscan2
- OR6B2 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99401103; called by muse, varscan2
- OR8H3 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100538699; called by muse, mutect2, varscan2
- PMS2 | c.29A>C p.E10A | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.884); catalogued as rs878854050, COSV99763807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD1 | c.1148T>C p.L383P | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as COSV101037191; called by muse, mutect2, varscan2
- PUM3 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.474); catalogued as rs558845198, COSV101193094; called by muse, mutect2, varscan2
- SARS1 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320878; called by muse, mutect2, varscan2
- SCN11A | c.2287C>T p.R763C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs537371340, COSV56573728; called by muse, mutect2, varscan2
- SIGLEC8 | c.365A>G p.Y122C | Missense Mutation (SNP) | VAF 56/85 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100367139; called by muse, mutect2, varscan2
- SLC4A1 | c.1265C>A p.T422N | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52262021; called by muse, mutect2, varscan2
- TAAR9 | c.671C>T p.A224V | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs558339339, COSV101453279; called by muse, mutect2, varscan2
- TRPM1 | c.4403C>T p.T1468M | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.776); catalogued as rs753584603, COSV99855224; called by muse, mutect2
- TTN | c.19622C>G p.S6541C (on ENST00000591111; = p.S5614C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | PolyPhen benign (0.416); catalogued as COSV100591847; called by muse, mutect2, varscan2
- ZNF621 | c.851T>G p.I284S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100182580; called by muse, mutect2, varscan2
- ZNF761 | c.763C>T p.R255* | Nonsense Mutation (SNP) | VAF 50/81 reads (62%) | catalogued as rs762002012, COSV100483241; called by muse, mutect2, varscan2
- ATRX | c.3904dup p.R1302Kfs*7 | Frame Shift Ins (INS) | VAF 39/61 reads (64%) | called by mutect2, varscan2
- CCNG2 | c.271dup p.M91Nfs*6 | Frame Shift Ins (INS) | VAF 10/82 reads (12%) | called by mutect2, pindel
- CLSTN3 | c.704_742+1del | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel
- DLG4 | c.2172_2173del p.*725Ifs*43 (on ENST00000399506 / NM_001321075.3; = p.*768Ifs*43 on NM_001365.4) | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | called by pindel, varscan2
- BCORL1 | c.4996C>T p.L1666= | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as COSV99498284; called by muse, mutect2, varscan2
- CABIN1 | c.2328G>A p.E776= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV99572603; called by muse, mutect2
- CNGB3 | c.1266T>C p.F422= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as COSV100181075; called by muse, mutect2, varscan2
- GRM4 | c.744G>A p.V248= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100945638; called by muse, mutect2, varscan2
- HMCN1 | c.6417A>G p.K2139= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV99623275; called by muse, mutect2
- MAGEC1 | c.777T>A p.T259= | Silent (SNP) | VAF 80/107 reads (75%) | catalogued as COSV53582527, COSV99594727; called by muse, mutect2, varscan2
- NIBAN3 | c.1392C>T p.L464= | Silent (SNP) | VAF 70/159 reads (44%) | catalogued as rs756733224, COSV56306085; called by muse, mutect2, varscan2
- NRP2 | c.2175C>G p.G725= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV99783362; called by muse, mutect2
- OR1A2 | c.612C>T p.G204= | Silent (SNP) | VAF 164/208 reads (79%) | catalogued as rs1006440504, COSV101126334; called by muse, mutect2, varscan2
- OR2L3 | c.30T>C p.D10= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV100741903; called by muse, mutect2
- OR6S1 | c.561G>T p.L187= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1196490752, COSV100289245; called by muse, mutect2
- PELI3 | c.1095C>T p.V365= | Silent (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100291679; called by muse, mutect2, varscan2
- THEMIS2 | c.249C>T p.P83= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV100197857; called by muse, mutect2, varscan2
- MIR124-1 | n.10_13del | RNA (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
